Surgical pathology report (de-identified scan), TCGA case TCGA-AK-3426, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Fox Chase, specimen TCGA-AK-3426-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

Clinical History/Diagnosis: Right renal mass

Source of Specimen(s):

- A: inter aorto caval Lymph Nodes
- B: right kidney adrenal gland hilar lymph nodes
- C: Retrocaval lymph nodes
- D: Additional retrocaval lymph nodes

Gross Description:

Received in four parts.

Source of Tissue: 1. Labeled #1, Inter-aortocaval lymph node .

Frozen Section Diagnosis: 1FS DIAGNOSIS DEFERRED, ? METASTASIS VERSUS PRIMARY TUMOR IN LYMPH VERSUS INTRANODAL VASCULAR PROLIFERATION,

Gross Description: Received fresh for frozen section evaluation is a 2.5cm in greatest dimension, tan-pink, firm lymph node which is sectioned to reveal bulging, nodular, cut surfaces. A representative section is submitted for frozen section evaluation and the frozen section residue is submitted in one block. Additional representative sections are submitted in two blocks.

Designation of Sections: 1FS, 1A-1B

Summary of Sections: multiple

Note: Tissue is submitted for microbiology cultures.

Source of Tissue: 2. Labeled #2, Right kidney, adrenal gland and hilar lymph nodes .

Frozen Section Diagnosis: 2FS RENAL CELL CARCINOMA PRESENT. THE FROZEN SECTION FROM PART #1 WAS RE-REVIEWED AFTER LOOKING AT THE FROZEN SECTION FROM THE KIDNEY. THAT IS METASTATIC CANCER FROM KIDNEY AND LYMPH NODE.

Gross Description: Received fresh for frozen section evaluation is an 879 gram, right nephrectomy, having an abundant amount of attached perinephric fat. There is a 1.5 x 0.3cm fragment of attached ureter, having a lumen, 0.2cm in greatest dimension which is probe patent to the renal hilum. The kidney itself is 16.0 x 6.5 x 5.0cm in greatest dimension. It is bivalved to reveal an 8.5 x 7.5 x 6.0cm mass in the mid to lower pole, having light tan to golden yellow-orange, nodular, cut surfaces. A representative section of the mass is submitted for frozen section evaluation and the frozen section residue is submitted in one block. The remaining renal

[page 2 of 3]
parenchyma is red-brown, firm, having a well-defined corticomedullary junction. The adrenal gland is 4.5 x 2.0 x 0.8cm in greatest dimension and is sectioned to reveal golden yellow-orange to tan-brown, cut surfaces. There is one palpable lymph node in the attached hilar soft tissue, 2.0cm in greatest dimension. The lymph node is entirely submitted. Representative sections are submitted in twelve blocks.

Designation of Sections: 2FS frozen section kidney mass, 2A ureter and vascular margins, 2B-2D tumor with inked circumferential margin, 2E-2F additional representative sections tumor, 2G-2H random sections kidney, 2I adrenal gland, 2J-2L hilar lymph node, 2M- additional ureteral margin.

Summary of Sections: multiple

Note: Tissue is submitted for cytogenetic studies.

Source of Tissue: 3. Labeled #3, Retrocaval lymph nodes .

Gross Description: Received fresh are two red-purple, firm lymph nodes, 4.0cm in greatest dimension. The lymph nodes are entirely submitted in five blocks.

Designation of Sections: 3A-3B one lymph node, 3C-3E one lymph node

Summary of Sections: multiple

**

Source of Tissue: 4. Labeled #4, Additional retrocaval lymph nodes .

Gross Description: Received fresh are six tan to red-purple, firm lymph nodes, 0.8 to 5.5cm in greatest dimension. The lymph nodes are sectioned to reveal red-purple to tan, soft, friable, cut surfaces. Representative sections are submitted in five blocks.

Designation of Sections: 4A-4B representative sections large lymph node, 4C one lymph node, 4D-4E multiple single lymph nodes.

Summary of Sections: multiple

Final Diagnosis:

1. Lymph node, inter-aortocaval, excision:
- Metastatic renal cell carcinoma in one lymph node (1/1).
2. Right kidney, adrenal gland and hilar lymph nodes, radical nephrectomy:

[page 3 of 3]
- High grade renal cell carcinoma (8.5 cm), nuclear grade 3; see note.
- Negative capsule and vascular margin.
- Ureteral margin with intralymphatic tumor emboli.
- Metastatic renal cell carcinoma in peri hilar soft tissue.
- Adrenal gland with no tumor seen.

3. Lymph nodes, retrocaval, excision:

- Metastatic renal cell carcinoma in two out of two lymph nodes (2/2).

4. Lymph nodes, retrocaval, excision:

- Metastatic renal cell carcinoma in three out of seven lymph nodes (3/7).

Note: The tumor morphologically shows clear cell and papillary features, with focal spindled cells suggestive of sarcomatoid change.

Immunohistochemistry stains show that the tumor cells are positive for CK7, HMW cytokeratin () and CD10. Final subtyping is pending cytogenetic analysis.

These tests were developed and their performance characteristics determined by the immunohistochemistry laboratory at the . These tests have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of (CLIA) as qualified to perform high complexity clinical testing.

Procedures/Addenda
FC Cytogenetics

Results-Comments
CYTOGENETIC ANALYSIS REPORTS

KARYOTYPE:

Abnormal mosaic karyotype: 36-44,XY,del(3)(p21p25),-8[cp20]
/46,XY[1]

RESULTS:

A renal mass was received and harvested after six and seven days in culture.

The chromosomes from 21 metaphases were counted and analyzed, and five of these metaphases were karyotyped by G-banding. Twenty cells had chromosome numbers ranging from 36 to 44 and exhibited two clonal aberrations: a deletion in the p arm of chromosome 3 and a missing copy of chromosome 8. Both of these abnormalities have been reported in cases of nonpapillary renal cell carcinoma. One cell had a normal karyotype. A preliminary report was given to

Source: NCI Genomic Data Commons file 81ffee1b-b434-45ca-a950-0ea90bb5eb50 (TCGA-AK-3426.4AE755F9-C7F3-4C42-859D-5D9407CDF3AC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).